Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A94W, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A94W-01A (Primary Tumor).

ICD O3
Carcinoma, squamous cell NOS
Site Cervix NOS C53.9
8070/3
QW 3/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1-"Biopsy of uterine cervix":

- Squamous cell carcinoma, invasive.

Addendum:

Histologic grade: moderately differentiated.

Sanguineous and lymphatic vascular infiltrations not detected.

Source: NCI Genomic Data Commons file c67dfd05-c1ec-44ab-a232-12ce90e2f319 (TCGA-VS-A94W.D7BD2CF8-068E-4D77-B4C3-8C51BD7A71CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).